Surgical pathology report (de-identified scan), TCGA case TCGA-HW-8322, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site MSKCC, specimen TCGA-HW-8322-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

Left frontal, low grade glioma seizures.

Specimens Submitted:

- 1: Left frontal brain tumor, biopsy
2: Left frontal lobe brain tumor, biopsy

DIAGNOSIS:

1. Left frontal brain tumor, biopsy:

Part # 1

TUMOR TYPE:

Oligodendroglioma

WHO GRADE:

II

2. Left frontal lobe brain tumor, biopsy:

Part # 2

TUMOR TYPE:

Oligodendroglioma

WHO GRADE:

II

MOLECULAR TESTING / IMMUNOHISTOCHEMISTRY:

1p/19q FISH has been ordered and results will be issued in a separate report

Comment: An immunostain for MIB-1 has been ordered and will be reported in an addendum

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result

Special Stain
MIB-1 (Ki-67)
IDH1-H09
RECUT
IMM RECUT
NEG CONT

Comment

[page 2 of 2]
Gross Description:

1) The specimen is received fresh for frozen section consultation, labeled "Left frontal brain tumor", and consists of two fragments of gray tan friable soft tissue measuring 1.2 x 0.6 x 0.5 cm in aggregate. Entirely submitted for smear and frozen section diagnosis.

Summary of sections:
FSC - frozen section control

2). The specimen is received fresh labeled "left frontal lobe brain tumor" and consists of multiple tan to brown to white, glistening fragments of tissue measuring 2.1 x 1.4 x 0.4 cm in aggregate. The entire specimen is submitted.

Summary of sections:
U-Undesignated

Summary of Sections:

Part 1: Left frontal brain tumor biopsy

Block	Sect. Site	PCs
1	FSC	1

Part 2: Left frontal lobe brain tumor, biopsy

Block	Sect. Site	PCs
1	u	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Left frontal brain tumor : Glioma, favor oligodendroglioma, low-grade on representative section
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file a3a73afb-6c96-4f85-ad7b-14c05d33881c (TCGA-HW-8322.43AEA5C8-29EC-4F1E-B948-101B645B4CF1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).